Somatic mutation profile of tumor specimen HCM-BROD-0701-C43-06B (aliquot HCM-BROD-0701-C43-06B-01D-A83U-36) from HCMI case HCM-BROD-0701-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.1 years (27,073 days).
Specimen HCM-BROD-0701-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ceea93d-dd75-49a5-9298-3df0b89156d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0701-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0701-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35152a1f-2822-4109-ba80-4de75aba8379

The open-access MAF lists 1,954 somatic variants for this specimen: 1,252 protein-altering or splice-affecting, 626 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,152, Silent 626, Nonsense Mutation 66, Intron 47, Splice Region 12, 3'UTR 8, 5'UTR 7, 5'Flank 7, Frame Shift Del 7, Splice Site 6, In Frame Del 5, RNA 5.

Variants (750 of 1,954; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 170/473 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62716997, COSV62717384; called by muse, varscan2
- CFTR | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs80282562, CM1510237, CM910069, COSV99135925; ClinVar: pathogenic / drug response; called by muse, mutect2, varscan2
- DNAH5 | c.8030G>A p.R2677Q | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043448, CM1310742, COSV54226107; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KIT | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 414/578 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs121913513, CM133722, COSV55386593, COSV55412340; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- MMAB | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 117/237 reads (49%) | catalogued as rs369296618, CM061122; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.3979G>A p.E1327K | Missense Mutation (SNP) | VAF 229/489 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs373169422, CM021308; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPR2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 290/683 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777596, CM1312322, COSV61041918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POMT1 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 84/800 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149682171, CM142766; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC17A5 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 86/485 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs80338795, CM003476, COSV63288151; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3386C>T p.S1129L | Missense Mutation (SNP) | VAF 176/385 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs200430365; called by muse, mutect2, varscan2
- ABCA13 | c.9272C>T p.S3091L | Missense Mutation (SNP) | VAF 159/395 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs373448676; called by muse, mutect2, varscan2
- ABCC12 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs200607476; called by muse, mutect2, varscan2
- ACAN | c.6914C>T p.P2305L | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.072); catalogued as rs1209211363, COSV100718132; called by muse, mutect2, varscan2
- ACAP1 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996571307; called by muse, mutect2, varscan2
- ACD | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 164/460 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.268); catalogued as rs1442724652, COSV54667786; called by muse, mutect2, varscan2
- ACMSD | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51608262; called by muse, mutect2, varscan2
- ACOT11 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 68/406 reads (17%) | catalogued as rs780923132, COSV64896191, COSV99055113; called by muse, mutect2, varscan2
- ACP5 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs371116310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACRBP | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57524562; called by muse, mutect2, varscan2
- ACSBG1 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99357419; called by muse, mutect2
- ACSS3 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV99699644; called by muse, mutect2, varscan2
- ADAM7 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51534874; called by muse, mutect2, varscan2
- ADAM7 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.191); catalogued as COSV51537081; called by muse, mutect2, varscan2
- ADAM7 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs777631956, COSV51535626; called by muse, mutect2, varscan2
- ADAMTS12 | c.4449T>C p.C1483= | Splice Region (SNP) | VAF 32/162 reads (20%) | catalogued as rs1400246972; called by muse, mutect2, varscan2
- ADAMTS12 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 126/244 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs768629098, COSV61260883; called by muse, mutect2, varscan2
- ADAMTS8 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57297415, COSV57298308; called by muse, mutect2, varscan2
- ADAP1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs1387064202; called by muse, mutect2, varscan2
- ADGRE3 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 196/367 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs774415927, COSV99505781; called by muse, mutect2, varscan2
- ADGRG5 | c.1506G>A p.W502* | Nonsense Mutation (SNP) | VAF 78/292 reads (27%) | catalogued as rs148556945; called by muse, mutect2, varscan2
- ADGRG7 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56295570; called by muse, mutect2, varscan2
- ADGRL3 | c.2855G>A p.G952E (on ENST00000506720 / NM_001322402.2; = p.G884E on NM_015236.6) | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72232266; called by muse, mutect2, varscan2
- ADGRV1 | c.9109C>T p.P3037S | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67984728; called by muse, mutect2, varscan2
- ADH1B | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100520839; called by muse, mutect2, varscan2
- ADH1C | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as rs759663608; called by muse, mutect2, varscan2
- AFM | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56919059, COSV56919350; called by muse, varscan2
- AGO1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as rs1203451050, COSV100940722; called by muse, mutect2, varscan2
- AGO4 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 187/450 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs377052492; called by muse, mutect2, varscan2
- AGR3 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 91/311 reads (29%) | catalogued as rs757738802; called by muse, mutect2, varscan2
- AGTPBP1 | c.2428C>T p.H810Y (on ENST00000357081 / NM_001330701.2; = p.H770Y on NM_015239.2) | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs267602296, COSV61269106; called by muse, mutect2, varscan2
- AKAP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 146/219 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs147442985, COSV62073813; called by muse, mutect2, varscan2
- ALMS1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 161/504 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs373979607; ClinVar: uncertain significance; called by muse, varscan2
- ANHX | c.720G>A p.E240= | Splice Region (SNP) | VAF 58/175 reads (33%) | catalogued as rs1168710911, COSV101376519; called by muse, mutect2, varscan2
- ANK3 | c.12866G>A p.G4289E (on ENST00000280772 / NM_001320874.2; = p.G913E on NM_001149.3) | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55069134; called by muse, mutect2, varscan2
- ANKIB1 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 246/432 reads (57%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as COSV56063082; called by muse, mutect2, varscan2
- ANKRD11 | c.6290C>T p.P2097L | Missense Mutation (SNP) | VAF 166/522 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV56366418; called by muse, mutect2, varscan2
- ANKRD22 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905477; called by muse, mutect2, varscan2
- ANKRD7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs374194422; called by muse, mutect2, varscan2
- ANO6 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 188/321 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1452747064, COSV100264216; called by muse, mutect2, varscan2
- APOB | c.7579G>A p.D2527N | Missense Mutation (SNP) | VAF 129/373 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.159); catalogued as COSV51922271; called by muse, mutect2, varscan2
- APOBR | c.2542C>T p.P848S (on ENST00000431282; = p.P857S on NM_018690.4) | Missense Mutation (SNP) | VAF 110/470 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60488725; called by muse, varscan2
- ARHGEF19 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 244/647 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV54616953; called by muse, mutect2, varscan2
- ARID1A | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 190/502 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs1446535939, COSV61372824; called by muse, mutect2, varscan2
- ARID5A | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 85/684 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1477280422; called by muse, mutect2, varscan2
- ARID5A | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 294/849 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1339501509; called by muse, mutect2, varscan2
- ARL13A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 126/158 reads (80%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs770049224; called by muse, mutect2, varscan2
- ARPP21 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 144/436 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51795289; called by muse, mutect2, varscan2
- ARRDC4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs17856817; called by muse, mutect2, varscan2
- ASB12 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 177/251 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV62857741; called by muse, mutect2, varscan2
- ASB14 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 145/371 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs550795726, COSV55700595; called by muse, mutect2, varscan2
- ASH2L | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99166980; called by muse, mutect2, varscan2
- ASXL3 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52473696, COSV99324754; called by muse, mutect2, varscan2
- ATG2A | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV65967015; called by muse, mutect2, varscan2
- ATP13A4 | c.3408G>A p.W1136* | Nonsense Mutation (SNP) | VAF 117/266 reads (44%) | catalogued as COSV61320162; called by muse, mutect2, varscan2
- ATP1A4 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 235/488 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1338469550, COSV63624383; called by muse, mutect2, varscan2
- ATP2B1 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs965242753; called by muse, varscan2
- ATP6V1A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs1283020403, COSV56362506; called by muse, mutect2, varscan2
- ATP8A2 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1299777316; called by muse, mutect2, varscan2
- B4GALNT4 | c.3085C>T p.R1029C | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs761296036, COSV100327968; called by muse, mutect2, varscan2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 235/645 reads (36%) | catalogued as COSV52287479; called by muse, varscan2
- BAIAP3 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs891288975, COSV50103590, COSV99136171; called by muse, mutect2, varscan2
- BCL11A | c.1109C>T p.P370L (on ENST00000335712 / NM_001365609.1; = p.P404L on NM_018014.4) | Missense Mutation (SNP) | VAF 271/570 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1302345071, COSV59629809; called by muse, varscan2
- BCLAF1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV62140252; called by muse, mutect2, varscan2
- BCOR | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 231/327 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60708534; called by muse, mutect2, varscan2
- BIRC6 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.287); catalogued as rs773766988; called by muse, mutect2, varscan2
- BLNK | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 138/329 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV99813759; called by muse, mutect2, varscan2
- BLNK | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs782231780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP1 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV100115365; called by muse, mutect2, varscan2
- BMP5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147691986; called by muse, mutect2, varscan2
- BMP8B | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1419497449; called by muse, mutect2, varscan2
- BOD1L1 | c.4580A>G p.D1527G | Missense Mutation (SNP) | VAF 104/434 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779278463; called by muse, mutect2, varscan2
- BRDT | c.542T>C p.F181S | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as rs758746905; called by muse, mutect2, varscan2
- BSN | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 277/932 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56516802; called by muse, mutect2, varscan2
- BSN | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 192/554 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs766014933, COSV56513405; called by muse, mutect2, varscan2
- BTK | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 103/156 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as CD972098; called by muse, mutect2, varscan2
- C12orf4 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.089); catalogued as rs769585720; called by muse, mutect2, varscan2
- C1R | c.1790C>T p.T597I (on ENST00000536053 / NM_001354346.2; = p.T583I on NM_001733.7) | Missense Mutation (SNP) | VAF 94/473 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs759255819; called by muse, mutect2, varscan2
- C22orf42 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 176/488 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.728); catalogued as COSV101173268; called by muse, mutect2, varscan2
- C2CD6 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as rs868075879, COSV53794494, COSV53803062; called by muse, mutect2, varscan2
- C2orf74 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 90/255 reads (35%) | catalogued as rs376938479, COSV67041621; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 198/375 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- C4orf54 | c.2968C>T p.L990F | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1246779508; called by muse, mutect2, varscan2
- C6orf58 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100315098; called by muse, mutect2, varscan2
- C7orf57 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 110/394 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs767919671, COSV100817210; called by muse, mutect2, varscan2
- C9orf43 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 150/575 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs770388466; called by muse, mutect2, varscan2
- C9orf43 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 151/575 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs778399315; called by muse, mutect2, varscan2
- CA10 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 42/588 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.253); catalogued as rs763461140; called by muse, mutect2
- CACNA1C | c.6062G>A p.R2021K (on ENST00000399634 / NM_001167625.1; = p.R1950K on NM_000719.7) | Missense Mutation (SNP) | VAF 286/556 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs773787202; called by muse, mutect2, varscan2
- CACNA1G | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 806/1009 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs373099107; called by muse, mutect2, varscan2
- CADPS2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100465351; called by muse, mutect2, varscan2
- CALD1 | c.2002C>T p.Q668* (on ENST00000361675 / NM_033138.4; = p.Q413* on NM_004342.7) | Nonsense Mutation (SNP) | VAF 123/500 reads (25%) | catalogued as COSV62645946; called by muse, mutect2, varscan2
- CAPZA3 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1335802532; called by muse, mutect2, varscan2
- CARD11 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 262/801 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV62755528, COSV62756795; called by muse, mutect2, varscan2
- CARD6 | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 253/439 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99620117; called by muse, mutect2, varscan2
- CATSPERB | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs139686935; called by muse, mutect2, varscan2
- CC2D1A | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 188/334 reads (56%) | catalogued as rs756869849; called by muse, varscan2
- CCDC174 | c.656A>T p.E219V | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771345868, COSV57980884; called by muse, mutect2, varscan2
- CCER1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 129/641 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100727100, COSV62647956; called by muse, mutect2, varscan2
- CCER1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as rs748293418; called by muse, mutect2, varscan2
- CCT8L2 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1196968491; called by muse, mutect2, varscan2
- CD101 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 196/341 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV56720225; called by muse, mutect2, varscan2
- CD1A | c.120G>A p.W40* | Nonsense Mutation (SNP) | VAF 197/726 reads (27%) | catalogued as rs866676954, COSV99192238; called by muse, mutect2, varscan2
- CD86 | c.73C>T p.P25S (on ENST00000330540 / NM_175862.5; = p.P19S on NM_006889.4) | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773800947; called by muse, mutect2, varscan2
- CDC16 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 225/491 reads (46%) | catalogued as rs763358911; called by muse, mutect2, varscan2
- CDC27 | c.1271A>T p.N424I | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV50369664; called by muse, mutect2, varscan2
- CDH12 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.386); catalogued as COSV101200705; called by muse, mutect2, varscan2
- CDH6 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV99418144; called by muse, mutect2, varscan2
- CDH9 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 146/284 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50257951; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4997C>T p.S1666L | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs763392632; called by muse, mutect2, varscan2
- CEACAM8 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs765531872, COSV54991576; called by muse, mutect2, varscan2
- CELA3B | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 202/607 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299197364, COSV61403442; called by muse, mutect2, varscan2
- CELSR2 | c.7541C>T p.S2514F | Missense Mutation (SNP) | VAF 145/288 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54774084; called by muse, mutect2, varscan2
- CELSR3 | c.7950G>A p.W2650* | Nonsense Mutation (SNP) | VAF 238/511 reads (47%) | catalogued as COSV50846376; called by muse, mutect2, varscan2
- CERS4 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99250710; called by muse, mutect2, varscan2
- CFAP74 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 239/568 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.881); catalogued as COSV54575108; called by muse, mutect2
- CFH | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as COSV66407548; called by muse, mutect2, varscan2
- CFHR5 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV99890026; called by muse, mutect2, varscan2
- CHODL | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs571904993; called by muse, mutect2, varscan2
- CHRM2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 145/620 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57780539; called by muse, mutect2, varscan2
- CLDN19 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 338/858 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.558); catalogued as rs549476247, COSV99591743; called by muse, mutect2, varscan2
- CLEC16A | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.199); catalogued as rs751411424; called by muse, mutect2, varscan2
- CNMD | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 222/482 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs372845189; called by muse, mutect2, varscan2
- CNTN5 | c.2345G>A p.G782E | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200401604; called by muse, mutect2, varscan2
- CNTNAP2 | c.3521G>C p.G1174A | Missense Mutation (SNP) | VAF 366/651 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454096594, COSV62160674; called by muse, mutect2, varscan2
- CNTNAP5 | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70482671; called by muse, mutect2, varscan2
- COL19A1 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs757943951; called by muse, mutect2, varscan2
- COL4A1 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 120/496 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1513266, COSV65432896; called by muse, mutect2, varscan2
- COL4A1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 133/474 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773980580; called by muse, mutect2, varscan2
- COL5A2 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 109/385 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV66406819, COSV66414106; called by muse, mutect2, varscan2
- COL7A1 | c.5032C>T p.P1678S | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV60395526; called by muse, mutect2, varscan2
- COL9A1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV100295159; called by muse, mutect2, varscan2
- COPS3 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV99253407; called by muse, mutect2, varscan2
- CPXM2 | c.2083G>A p.G695S | Missense Mutation (SNP) | VAF 226/437 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53872270; called by muse, mutect2, varscan2
- CPXM2 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 53/355 reads (15%) | catalogued as rs138440648; called by muse, mutect2, varscan2
- CR1 | c.5009C>T p.S1670L | Missense Mutation (SNP) | VAF 139/349 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV65461521; called by muse, mutect2, varscan2
- CRB1 | c.3044G>A p.G1015D | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1558137862; called by muse, varscan2
- CRNN | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 398/742 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV55122932; called by muse, mutect2, varscan2
- CRTAC1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 152/551 reads (28%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.467); catalogued as rs771262267, COSV100085382; called by muse, mutect2, varscan2
- CSGALNACT2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 104/430 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752990408, COSV65676403; called by muse, mutect2, varscan2
- CSMD2 | c.4498C>T p.H1500Y | Missense Mutation (SNP) | VAF 202/477 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV53964406; called by muse, mutect2, varscan2
- CTBP1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 302/554 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs765846448; called by muse, mutect2, varscan2
- CTC1 | c.3473C>T p.S1158F | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59855913; called by muse, mutect2, varscan2
- CYP11B1 | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as CM1310228; called by muse, mutect2, varscan2
- DCAF8L1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 176/229 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs769053531, COSV71595254, COSV71595276; called by muse, mutect2, varscan2
- DCAF8L2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 264/356 reads (74%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1210887159, COSV70548788; called by muse, varscan2
- DCST2 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 154/608 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1321842318; called by muse, mutect2, varscan2
- DDIT4L | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 89/240 reads (37%) | catalogued as rs144358521, COSV56767313; called by muse, mutect2, varscan2
- DDX60L | c.4619C>T p.P1540L | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758055716; called by muse, mutect2, varscan2
- DGUOK | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1407707707; called by muse, mutect2, varscan2
- DHX15 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 207/376 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025627; called by muse, mutect2, varscan2
- DMBT1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1453665039; called by muse, mutect2, varscan2
- DNAAF2 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 426/740 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169233962, COSV53569817; called by muse, mutect2, varscan2
- DNAH10 | c.12529G>C p.D4177H (on ENST00000409039; = p.D4116H on NM_207437.3) | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68998586; called by muse, varscan2
- DNAH3 | c.9604C>T p.Q3202* | Nonsense Mutation (SNP) | VAF 134/272 reads (49%) | catalogued as rs1389550862; called by muse, mutect2, varscan2
- DNAH7 | c.5650C>T p.R1884* | Nonsense Mutation (SNP) | VAF 41/295 reads (14%) | catalogued as rs201461887; called by muse, mutect2, varscan2
- DNAH8 | c.5591G>A p.G1864E | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59479008; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2, varscan2
- DOT1L | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67110732; called by muse, mutect2, varscan2
- DPF3 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.108); catalogued as COSV63500147, COSV99057249; called by mutect2, varscan2
- DPY19L2 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.374); catalogued as COSV60542509; called by muse, mutect2, varscan2
- DSG4 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 190/444 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs778506958; called by muse, mutect2, varscan2
- DUXA | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs777400385, COSV73729530; called by muse, mutect2, varscan2
- DVL1 | c.1811C>T p.S604L (on ENST00000378888 / NM_001330311.2; = p.S579L on NM_004421.3) | Missense Mutation (SNP) | VAF 257/671 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs377189378; called by muse, mutect2, varscan2
- EDAR | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 174/453 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471093049; called by muse, mutect2, varscan2
- EDIL3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1218864909; called by muse, varscan2
- EDN2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 213/576 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs779966886; called by muse, mutect2, varscan2
- ELAPOR1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 188/299 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64043970; called by muse, mutect2, varscan2
- EMILIN1 | c.1967C>T p.S656F | Missense Mutation (SNP) | VAF 236/493 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754519478; called by muse, mutect2, varscan2
- EML6 | c.1993C>G p.P665A | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs566644936; called by muse, mutect2, varscan2
- EPHA8 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 309/675 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750964170; called by muse, mutect2, varscan2
- EPS8L3 | c.1526C>T p.P509L (on ENST00000361965 / NM_133181.4; = p.P479L on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs868605570; called by muse, mutect2, varscan2
- ERBB3 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs1281839539; called by muse, mutect2, varscan2
- ERBB4 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 127/465 reads (27%) | catalogued as COSV53501228; called by muse, mutect2, varscan2
- ERICH3 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58616127; called by muse, mutect2, varscan2
- ESPL1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs778397020; called by muse, mutect2, varscan2
- ETV3L | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 143/473 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs748750472; called by muse, mutect2, varscan2
- FAM162A | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as COSV51657644; called by muse, mutect2, varscan2
- FBLN2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 300/662 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1224816581; called by muse, mutect2, varscan2
- FBN1 | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as CD157734; called by muse, mutect2, varscan2
- FBXL5 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 155/287 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100377718; called by muse, mutect2, varscan2
- FBXO46 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 327/628 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1416318404; called by muse, mutect2, varscan2
- FER1L5 | c.2647C>T p.R883W (on ENST00000623019; = p.R888W on NM_001293083.2) | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1251119530; called by muse, mutect2, varscan2
- FHDC1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 169/534 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs748345501; called by muse, mutect2, varscan2
- FILIP1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 197/352 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1046337978, COSV52724428; called by muse, mutect2, varscan2
- FLG | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 285/564 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs1557882793; called by muse, mutect2, varscan2
- FLT1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 132/459 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766489043, COSV56724787; called by muse, mutect2, varscan2
- FLT4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs199942873, COSV56123360; called by muse, mutect2, varscan2
- FMNL2 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV56495251; called by muse, mutect2, varscan2
- FMO3 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV63007996; called by muse, mutect2, varscan2
- FMR1NB | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 86/122 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100789542, COSV63272986; called by muse, mutect2, varscan2
- FOXM1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 222/421 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs138164446; called by muse, mutect2, varscan2
- FOXS1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 334/610 reads (55%) | SIFT tolerated (1); PolyPhen possibly damaging (0.665); catalogued as rs757397108, COSV54067232; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 180/351 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FRY | c.6940C>T p.R2314* | Nonsense Mutation (SNP) | VAF 37/484 reads (8%) | catalogued as COSV66583342; called by muse, mutect2
- FUT7 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 112/922 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs375415626; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 148/253 reads (58%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FXR2 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs767339071; called by muse, mutect2, varscan2
- GABPB1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV99589939; called by muse, mutect2, varscan2
- GALNT2 | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV64194959; called by mutect2, varscan2
- GBP3 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750980387; called by muse, mutect2, varscan2
- GIMAP8 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 270/537 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs770094053, COSV56230411; called by muse, mutect2, varscan2
- GK2 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs377582691; called by muse, mutect2, varscan2
- GK3P | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs534976903; called by muse, mutect2, varscan2
- GLYATL1 | c.737G>A p.R246Q (on ENST00000317391 / NM_001354699.1; = p.R277Q on NM_080661.4) | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs986110866, COSV55610683; called by muse, mutect2, varscan2
- GPAT3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52357342; called by muse, mutect2, varscan2
- GPC1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 121/486 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs565369538; called by muse, mutect2, varscan2
- GPR119 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 148/202 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52276567; called by muse, mutect2, varscan2
- GPR12 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 164/548 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV67344965; called by muse, mutect2, varscan2
- GPR135 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 375/719 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs776476442, COSV67749758; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPRIN1 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759159223; called by muse, varscan2
- GRAMD1B | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs759398423, COSV59202274, COSV59209107; called by muse, mutect2, varscan2
- GRIA4 | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV56888644; called by muse, mutect2, varscan2
- GRIN2B | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV101662975, COSV74205904; called by muse, mutect2, varscan2
- GRM4 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 205/360 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV65220381; called by muse, mutect2, varscan2
- GRM8 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 103/477 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as rs1021001584, COSV58815708; called by muse, mutect2, varscan2
- GRM8 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 133/549 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.274); catalogued as rs750614819, COSV58833121; called by muse, mutect2, varscan2
- GSS | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53811843, COSV99404527; called by muse, varscan2
- GSTM5 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1482687783, COSV99859790; called by muse, mutect2, varscan2
- GSTO1 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 140/317 reads (44%) | catalogued as COSV100866920; called by muse, mutect2, varscan2
- GYS2 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380022003; called by muse, varscan2
- H1-7 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 312/580 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1212008905, COSV58601927; called by muse, mutect2
- H1-7 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 400/671 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100622150, COSV58602196; called by muse, mutect2, varscan2
- H2BW1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 89/114 reads (78%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs369212037; called by muse, mutect2, varscan2
- HEPACAM | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs542132168, COSV53428520; called by muse, mutect2, varscan2
- HEPHL1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV59890563; called by muse, mutect2, varscan2
- HEPHL1 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.168); catalogued as rs1235991160, COSV59892497; called by muse, mutect2, varscan2
- HERC1 | c.8800C>T p.L2934F | Missense Mutation (SNP) | VAF 136/380 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1456715895, COSV101496899; called by muse, mutect2, varscan2
- HHIP | c.981C>T p.S327= | Splice Region (SNP) | VAF 87/254 reads (34%) | catalogued as COSV99667683; called by muse, mutect2, varscan2
- HIBCH | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs750514913; called by muse, mutect2, varscan2
- HIVEP1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65102439; called by muse, mutect2, varscan2
- HIVEP3 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 257/609 reads (42%) | catalogued as COSV56015299; called by muse, mutect2, varscan2
- HMCN1 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 115/259 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1187955244, COSV99635569; called by muse, mutect2, varscan2
- HMCN1 | c.10672C>T p.P3558S | Missense Mutation (SNP) | VAF 155/393 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54901969; called by muse, mutect2, varscan2
- HMCN1 | c.15514C>T p.R5172C | Missense Mutation (SNP) | VAF 132/535 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs554554647; called by muse, mutect2, varscan2
- HOXB1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs916641552, COSV53317166; called by muse, mutect2, varscan2
- HS3ST2 | c.817A>C p.S273R | Missense Mutation (SNP) | VAF 74/387 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99758435; called by muse, mutect2, varscan2
- HSD11B2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 103/292 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs781774610; called by muse, mutect2, varscan2
- HSD17B13 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1463383779, COSV56345865, COSV56347271; called by muse, mutect2, varscan2
- HSP90B1 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 175/344 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770752783, COSV55354474; called by muse, mutect2, varscan2
- HTR4 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 137/416 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs755406494, COSV58805920; called by muse, mutect2, varscan2
- HYDIN | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 93/496 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs753149194; called by muse, mutect2, varscan2
- IBSP | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 164/452 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs374954526; called by muse, mutect2, varscan2
- IFNW1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 151/229 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV66522337, COSV66522538; called by muse, mutect2, varscan2
- IGHA1 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773510471; called by mutect2, varscan2
- IGHV2-70 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs745462696; called by muse, mutect2
- IL1RL1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs267598807, COSV52116909; called by muse, varscan2
- IL2RB | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs865902855, COSV53427807; called by muse, mutect2, varscan2
- IL6ST | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs760817248; called by muse, mutect2, varscan2
- IL6ST | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1468519735; called by muse, varscan2
- INSYN2B | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs774178103, COSV56952974; called by muse, mutect2, varscan2
- IPMK | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.419); catalogued as rs746395205, COSV64243792; called by muse, mutect2, varscan2
- IPPK | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 357/782 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs532013075; called by muse, mutect2, varscan2
- IRAK3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 147/304 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV54165719; called by muse, mutect2, varscan2
- IRF2BPL | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 283/755 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99467833; called by muse, mutect2, varscan2
- ITGA4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201906563, COSV51998072; called by muse, mutect2, varscan2
- ITGA4 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV51999131; called by muse, mutect2, varscan2
- ITGAD | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 94/355 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV66757311; called by muse, mutect2, varscan2
- ITPR1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057518026; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- IVL | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 612/1080 reads (57%) | catalogued as COSV64215594; called by muse, mutect2, varscan2
- JCAD | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 199/280 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as rs766180970, COSV64760102; called by muse, mutect2, varscan2
- KANK4 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1311511403; called by muse, mutect2, varscan2
- KBTBD12 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs746436381; called by muse, mutect2, varscan2
- KBTBD12 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 177/407 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751053641, COSV59678733; called by muse, mutect2
- KCNC2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 103/584 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54369344; called by muse, mutect2, varscan2
- KCNC2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 95/518 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371497523, COSV54361561; called by muse, mutect2, varscan2
- KCNJ1 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 151/365 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.718); catalogued as rs762542207; called by muse, mutect2, varscan2
- KCNMA1 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV99699078; called by muse, mutect2, varscan2
- KCTD9 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV99648399; called by muse, mutect2, varscan2
- KEL | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 185/712 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV62333348; called by muse, mutect2, varscan2
- KIAA1549L | c.2632C>T p.H878Y (on ENST00000321505; = p.H1175Y on NM_012194.3) | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.731); catalogued as rs747383231, COSV55779907; called by muse, mutect2, varscan2
- KIF14 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.022); catalogued as rs1045969869; called by muse, mutect2, varscan2
- KIF17 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 173/466 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56117295; called by muse, mutect2, varscan2
- KIF2B | c.366A>T p.K122N | Missense Mutation (SNP) | VAF 82/919 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV52128804; called by muse, mutect2
- KMT2C | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 305/553 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV51298137; called by muse, mutect2, varscan2
- KNL1 | c.1837C>T p.P613S (on ENST00000346991 / NM_170589.5; = p.P587S on NM_144508.5) | Missense Mutation (SNP) | VAF 126/449 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs746667746; called by muse, mutect2, varscan2
- KRBOX1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs764901289, COSV67466928; called by muse, mutect2, varscan2
- KRTAP5-1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 91/491 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs756972764; called by muse, mutect2, varscan2
- L3MBTL3 | c.1708A>G p.K570E | Missense Mutation (SNP) | VAF 166/313 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs533560529; called by muse, mutect2, varscan2
- LAIR1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 279/544 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.081); catalogued as COSV57307395; called by muse, mutect2, varscan2
- LAMA2 | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 160/333 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145940188; called by muse, mutect2, varscan2
- LAMB2 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 143/522 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV59732540, COSV59737593; called by muse, mutect2, varscan2
- LAMB4 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 260/464 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1336696238, COSV52715160; called by muse, mutect2, varscan2
- LCT | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 192/443 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.158); catalogued as rs770200258, COSV51549946; called by muse, mutect2, varscan2
- LGI4 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1187137003, COSV100032760; called by muse, mutect2, varscan2
- LGR5 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV57009204; called by muse, mutect2, varscan2
- LHCGR | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs149019093, COSV54303658; called by muse, mutect2, varscan2
- LHX9 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 203/509 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1219028829; called by muse, mutect2, varscan2
- LILRA4 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52492751; called by muse, mutect2, varscan2
- LITAF | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs774532093, COSV100243243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNTD1 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as rs1279653696; called by muse, mutect2, varscan2
- LOXHD1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 218/576 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs631046, COSV100190824; called by muse, mutect2, varscan2
- LPA | c.3779C>T p.S1260F | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.664); catalogued as rs1382626254; called by muse, mutect2, varscan2
- LPAR4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 179/247 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606517, COSV70912599; called by muse, mutect2, varscan2
- LPCAT2 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1319427156; called by muse, mutect2, varscan2
- LRCH4 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 121/478 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.74); catalogued as COSV53825993; called by muse, mutect2, varscan2
- LRRTM4 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 126/523 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV69138862; called by muse, mutect2, varscan2
- LYST | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV67714958; called by muse, mutect2, varscan2
- LYVE1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 150/320 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99810882; called by muse, mutect2, varscan2
- LZTFL1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 124/449 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944743; called by muse, mutect2, varscan2
- MAEL | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 247/496 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV63304191; called by muse, mutect2, varscan2
- MAGEA1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 154/203 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63118372; called by muse, mutect2, varscan2
- MAGI1 | c.4097C>T p.S1366F | Missense Mutation (SNP) | VAF 289/670 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.994); catalogued as rs747528094; called by muse, mutect2, varscan2
- MAP3K15 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58839092; called by muse, mutect2, varscan2
- MAP3K5 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62892806; called by muse, mutect2, varscan2
- MAP4 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 56/497 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138444567; called by muse, mutect2, varscan2
- MAP4K1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV101204457; called by muse, mutect2, varscan2
- MAST4 | c.1177G>A p.E393K (on ENST00000403625 / NM_001164664.2; = p.E204K on NM_015183.3) | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs773257003; called by muse, mutect2, varscan2
- MCEMP1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs139191722, COSV58039436; called by muse, mutect2, varscan2
- MCM5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 318/770 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs573739349; called by muse, mutect2, varscan2
- MCMDC2 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1304381881; called by muse, mutect2, varscan2
- MCPH1 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1031822642, COSV60912155; called by muse, mutect2, varscan2
- ME1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 102/191 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs1024613609, COSV63838552; called by muse, varscan2
- MEGF8 | c.4732C>T p.R1578C (on ENST00000251268 / NM_001271938.2; = p.R1511C on NM_001410.3) | Missense Mutation (SNP) | VAF 115/579 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs774288940; called by muse, mutect2, varscan2
- MFSD2A | c.1073C>T p.P358L (on ENST00000372809 / NM_001136493.3; = p.P345L on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 176/486 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368639501; called by muse, mutect2, varscan2
- MGAM | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 131/504 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101516333; called by muse, mutect2, varscan2
- MGAM2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 253/488 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs947608659; called by muse, mutect2, varscan2
- MMP21 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 297/651 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs1251452399, COSV64289053; called by muse, mutect2, varscan2
- MS4A4A | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 140/296 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs776125694, COSV59700874; called by muse, mutect2, varscan2
- MSH5 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 78/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1464099616; called by muse, mutect2, varscan2
- MUC16 | c.38996C>T p.S12999F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV67460482; called by muse, mutect2, varscan2
- MUC16 | c.33521C>T p.S11174F | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV67490666; called by muse, varscan2
- MUC16 | c.33512C>G p.T11171S | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as COSV67446093; called by muse, varscan2
- MUC16 | c.32698C>T p.P10900S | Missense Mutation (SNP) | VAF 166/317 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV67487944; called by muse, mutect2, varscan2
- MUC16 | c.31253C>T p.S10418L | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as COSV67473649; called by muse, mutect2, varscan2
- MUC16 | c.27374G>C p.R9125T | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.017); catalogued as rs544292988; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC16 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.486); catalogued as rs965434261; called by muse, mutect2, varscan2
- MUC16 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs765899813; called by muse, mutect2, varscan2
- MUC2 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); catalogued as COSV100365105; called by muse, mutect2, varscan2
- MX2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.426); catalogued as rs762150617; called by muse, mutect2, varscan2
- MYBPC1 | c.1345G>A p.E449K (on ENST00000550270 / NM_206820.2; = p.E474K on NM_002465.4) | Missense Mutation (SNP) | VAF 168/326 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV62252081, COSV62256429; called by muse, mutect2, varscan2
- MYBPC2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779252873, COSV100731604; called by muse, mutect2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH4 | c.5186A>G p.N1729S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as rs780182993; called by muse, mutect2, varscan2
- MYLK3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV67362876; called by muse, mutect2, varscan2
- MYO18B | c.5024C>T p.S1675L | Missense Mutation (SNP) | VAF 218/555 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1445932312; called by muse, mutect2, varscan2
- MYO5B | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs765443536, COSV53219306; called by muse, mutect2, varscan2
- MYO5B | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs765228902; called by muse, mutect2, varscan2
- MYPOP | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1345284604; called by muse, mutect2, varscan2
- NCKAP5 | c.2756G>A p.G919E | Missense Mutation (SNP) | VAF 181/446 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV58449704; called by muse, mutect2, varscan2
- NDUFV1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as rs767534263; called by muse, mutect2, varscan2
- NEBL | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 184/261 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1320937284; called by muse, mutect2, varscan2
- NELL1 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs778650800, COSV54334539; called by muse, mutect2, varscan2
- NID1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 168/553 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs774602095, COSV51621061; called by muse, mutect2, varscan2
- NID1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 120/469 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs563993834, COSV51621525; called by muse, mutect2, varscan2
- NLRP3 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 159/380 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs202204283, COSV60224527; called by muse, mutect2, varscan2
- NLRP9 | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as rs1482432307; called by muse, mutect2, varscan2
- NME7 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765735657; called by muse, mutect2, varscan2
- NOS1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs147820513, COSV57606244; called by muse, mutect2, varscan2
- NOTCH2 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV56705300; called by muse, mutect2, varscan2
- NOTCH4 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 87/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66681701; called by muse, varscan2
- NPAP1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.303); catalogued as rs1309188013, COSV100276000; called by muse, mutect2, varscan2
- NPY1R | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV56715891; called by muse, mutect2, varscan2
- NRAP | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.544); catalogued as COSV100748335; called by muse, mutect2, varscan2
- NRXN2 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449866; called by muse, mutect2, varscan2
- NRXN2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs1432184680, COSV55448205, COSV55463489; called by muse, mutect2, varscan2
- NSD2 | c.3376C>T p.R1126C | Missense Mutation (SNP) | VAF 116/406 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56386118, COSV56393221; called by muse, mutect2, varscan2
- NT5C1B | c.890C>T p.S297L (on ENST00000359846 / NM_001199086.2; = p.S237L on NM_033253.4) | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs1162482828; called by muse, varscan2
- NTRK3 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 141/401 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs1330829152; called by muse, mutect2, varscan2
- NTRK3 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58109641; called by muse, mutect2, varscan2
- NUTM2D | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as rs1467407009; called by mutect2, varscan2
- NYNRIN | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 534/833 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1325965983; called by muse, mutect2, varscan2
- OLFM3 | c.710G>A p.R237Q (on ENST00000338858 / NM_001288821.1; = p.R217Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/332 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58797459; called by muse, mutect2, varscan2
- OPN3 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs770842729, COSV59364204, COSV59364701; called by muse, mutect2, varscan2
- OR11H4 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59560167; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 246/465 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2F2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 291/582 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs768168444; called by muse, mutect2, varscan2
- OR2G3 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100180658; called by muse, mutect2, varscan2
- OR4A16 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs267602960, COSV59042565, COSV59042689; called by muse, mutect2, varscan2
- OR4N2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60050724; called by muse, mutect2, varscan2
- OR4S1 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679201; called by muse, mutect2, varscan2
- OR5J2 | c.887A>C p.D296A | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56623154; called by muse, mutect2, varscan2
- OR5T2 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763088731; called by muse, mutect2, varscan2
- OTOF | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158890871; called by muse, mutect2, varscan2
- OVCH2 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 147/395 reads (37%) | catalogued as rs775193800, COSV71953012; called by muse, mutect2, varscan2
- PAPPA | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 305/847 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV60278956, COSV60294813; called by muse, varscan2
- PAPPA | c.4501G>A p.E1501K | Missense Mutation (SNP) | VAF 160/369 reads (43%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.751); catalogued as COSV60290142; called by muse, mutect2, varscan2
- PAPSS2 | c.1310C>G p.P437R | Missense Mutation (SNP) | VAF 265/604 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753712; called by muse, mutect2, varscan2
- PAQR8 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 183/347 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1267231734; called by muse, mutect2, varscan2
- PARD3B | c.2317C>T p.R773* (on ENST00000406610 / NM_001302769.2; = p.R711* on NM_152526.6) | Nonsense Mutation (SNP) | VAF 140/445 reads (31%) | catalogued as rs781428613, COSV62508684; called by muse, varscan2
- PARP12 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54934039; called by muse, mutect2, varscan2
- PARP9 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 119/407 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs771068546; called by muse, mutect2, varscan2
- PAX8 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 162/523 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs779235186; called by muse, mutect2, varscan2
- PCDHAC2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV53846239; called by muse, varscan2
- PCDHB6 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 218/585 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs868915597, COSV50705762; called by muse, mutect2, varscan2
- PCDHB9 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 182/854 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1315810965, COSV53379024; called by muse, mutect2, varscan2
- PCF11 | c.3401C>T p.P1134L | Missense Mutation (SNP) | VAF 143/320 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377083731, COSV100019359; called by muse, mutect2, varscan2
- PCLO | c.11276G>A p.R3759Q | Missense Mutation (SNP) | VAF 157/596 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs777335223, COSV61660633; called by muse, mutect2, varscan2
- PCLO | c.5755G>A p.E1919K | Missense Mutation (SNP) | VAF 277/525 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61655590; called by muse, mutect2, varscan2
- PCSK5 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 182/638 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.087); catalogued as rs1375907269; called by muse, mutect2, varscan2
- PDE4B | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs944736576, COSV58476744; called by muse, mutect2, varscan2
- PDE4DIP | c.4223C>T p.S1408L | Missense Mutation (SNP) | VAF 114/642 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as COSV57686456; called by muse, mutect2
- PDZRN4 | c.2483C>T p.P828L (on ENST00000402685 / NM_001164595.2; = p.P570L on NM_013377.4) | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs373546139; called by muse, mutect2, varscan2
- PEAR1 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 206/700 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs902307219; called by muse, mutect2, varscan2
- PEG3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 217/403 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.428); catalogued as rs56332142, COSV99691402; called by muse, mutect2, varscan2
- PES1 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 130/339 reads (38%) | catalogued as rs748187531, COSV58828501; called by muse, mutect2, varscan2
- PHF3 | c.5326C>T p.P1776S | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1445822408, COSV50313855; called by muse, mutect2, varscan2
- PIK3R4 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs753937041; called by muse, mutect2, varscan2
- PJVK | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV64306950; called by muse, mutect2, varscan2
- PLAC8L1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1230983244; called by muse, mutect2
- PLAGL1 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 273/470 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs773466984; called by muse, mutect2, varscan2
- PLCB3 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201041817, COSV54191224, COSV99657393; called by muse, mutect2, varscan2
- PLCE1 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 292/647 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757905871; called by muse, mutect2, varscan2
- PLCH2 | c.3713G>A p.G1238D | Missense Mutation (SNP) | VAF 259/699 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); catalogued as rs768151035, COSV99615571; called by muse, mutect2, varscan2
- PLCXD3 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV60606911; called by muse, mutect2, varscan2
- PLEKHG4B | c.344G>A p.G115E (on ENST00000283426; = p.G471E on NM_052909.5) | Missense Mutation (SNP) | VAF 265/433 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52043712; called by muse, mutect2, varscan2
- PLXNA4 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 104/406 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV100323755; called by muse, mutect2, varscan2
- PLXNB2 | c.2260C>T p.H754Y | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs773637239; called by muse, mutect2, varscan2
- PNKP | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 153/283 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1301142821; called by muse, mutect2, varscan2
- POSTN | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs752238381, COSV65712189; called by muse, mutect2, varscan2
- POU5F1B | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 221/662 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1345486200; called by muse, mutect2, varscan2
- POU5F1B | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 198/593 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66966769; called by muse, mutect2, varscan2
- PPM1J | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 196/346 reads (57%) | SIFT tolerated (0.83); PolyPhen benign (0.139); catalogued as rs1284178949, COSV58551883; called by muse, mutect2, varscan2
- PPP1R18 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 133/672 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1263139967; called by muse, mutect2, varscan2
- PPP1R3A | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 112/468 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs62001880, COSV99492473; called by muse, varscan2
- PRB2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 345/676 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.839); catalogued as COSV66983017; called by muse, mutect2, varscan2
- PRB3 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 174/420 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs768625455, COSV54388919; called by muse, varscan2
- PRDM9 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 66/601 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1241376585, COSV99689592; called by muse, mutect2, varscan2
- PROS1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs121918476, CM057362, CM991071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS55 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60808986; called by muse, mutect2, varscan2
- PTCHD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59776225; called by muse, mutect2, varscan2
- PTPRT | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs759824186, COSV62037927; called by muse, mutect2, varscan2
- R3HDM4 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.027); catalogued as rs778251922; called by muse, varscan2
- RAB39A | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 223/479 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57695475; called by muse, mutect2, varscan2
- RALGPS2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 55/514 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100244067; called by muse, mutect2
- RASGRF1 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs770002588, COSV67249738, COSV67250135; called by muse, mutect2, varscan2
- RBBP6 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); catalogued as rs749340968; called by muse, mutect2, varscan2
- RBM19 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs766482551; called by muse, mutect2, varscan2
- RBM28 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 217/432 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56165069; called by muse, mutect2, varscan2
- RBM39 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53615214, COSV53616264, COSV99488189; called by muse, mutect2, varscan2
- RBMXL3 | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 228/317 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1198789715, COSV57759971; called by muse, mutect2, varscan2
- RCOR3 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 221/487 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.115); catalogued as rs766489829; called by muse, mutect2, varscan2
- REST | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 130/392 reads (33%) | catalogued as COSV58359578; called by muse, mutect2, varscan2
- RET | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 181/625 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.157); catalogued as rs1060500763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RETREG2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs945836180; called by muse, mutect2, varscan2
- RFNG | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 44/493 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1470129785, COSV57649094; called by muse, mutect2
- RGS7 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.597); catalogued as COSV58539993; called by muse, mutect2, varscan2
- RIMS2 | c.1720G>A p.D574N (on ENST00000666250 / NM_001348490.2; = p.D382N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765782930, COSV51652261, COSV99199638; called by muse, mutect2, varscan2
- RNF150 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 143/302 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs200661337, COSV60801700; called by muse, mutect2, varscan2
- RNF213 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 52/740 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60621986; called by muse, mutect2
- RNLS | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 172/421 reads (41%) | catalogued as rs764003438; called by muse, mutect2, varscan2
- ROBO3 | c.2076G>A p.V692= | Splice Region (SNP) | VAF 52/199 reads (26%) | catalogued as rs1027592197; called by muse, mutect2, varscan2
- ROS1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 188/356 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1451448120; called by muse, mutect2, varscan2
- RP1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 238/628 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55109883; called by muse, mutect2, varscan2
- RTP1 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 165/544 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751274424, COSV56617720, COSV56619021; called by muse, mutect2, varscan2
- RXFP1 | c.537-1G>A p.X179_splice | Splice Site (SNP) | VAF 81/246 reads (33%) | catalogued as rs754617777, COSV57055931; called by muse, mutect2, varscan2
- RXFP2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243388453, COSV53637789; called by muse, mutect2, varscan2
- RYR2 | c.14818G>A p.V4940I | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1558506940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs778995715, COSV101212541, COSV66784560; called by muse, mutect2, varscan2
- RYR3 | c.4807C>T p.R1603* | Nonsense Mutation (SNP) | VAF 141/435 reads (32%) | catalogued as rs560814484; called by muse, mutect2, varscan2
- SALL3 | c.2665C>G p.R889G | Missense Mutation (SNP) | VAF 261/669 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs1344893514; called by muse, mutect2, varscan2
- SASH3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 168/218 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs748844612; called by muse, mutect2, varscan2
- SCN1A | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 259/810 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs1553544581, COSV57663296, COSV57674595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3B | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs1219641193; called by muse, mutect2, varscan2
- SCRIB | c.4028C>T p.P1343L | Missense Mutation (SNP) | VAF 152/423 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs372941923; called by muse, mutect2, varscan2
- SCRT1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 143/293 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1000986647; called by muse, mutect2, varscan2
- SEC16A | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 100/970 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV51540420; called by muse, mutect2
- SEMA4F | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1026452681, COSV60285600; called by muse, mutect2, varscan2
- SERPINB4 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61985829; called by muse, mutect2, varscan2
- SERPIND1 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53137167; called by muse, mutect2, varscan2
- SETD6 | c.1051G>A p.E351K (on ENST00000219315 / NM_001160305.4; = p.E327K on NM_024860.3) | Missense Mutation (SNP) | VAF 155/408 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.264); catalogued as COSV50746566; called by muse, mutect2, varscan2
- SH2D3C | c.601C>T p.H201Y (on ENST00000314830 / NM_170600.3; = p.H44Y on NM_005489.4) | Missense Mutation (SNP) | VAF 176/543 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1177958298; called by muse, mutect2, varscan2
- SI | c.4075C>T p.H1359Y | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.027); catalogued as rs1298384483; called by muse, mutect2, varscan2
- SIGLEC12 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs1426292237, COSV52459882; called by muse, mutect2, varscan2
- SIGLEC9 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV99142460; called by muse, mutect2, varscan2
- SIGLECL1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57064446; called by muse, mutect2, varscan2
- SIPA1L3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 334/636 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0.229); catalogued as rs1462416248, COSV55914545; called by muse, mutect2, varscan2
- SLA2 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1190668272; called by muse, varscan2
- SLC12A6 | c.1688C>T p.T563I (on ENST00000354181 / NM_001365088.1; = p.T512I on NM_005135.2) | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs970501910; called by muse, mutect2, varscan2
- SLC1A6 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 246/433 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs141949887, COSV55669198; called by muse, mutect2, varscan2
- SLC22A18 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 132/295 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs371786058; called by muse, mutect2, varscan2
- SLC22A24 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs1234626877; called by muse, mutect2, varscan2
- SLC22A9 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 123/233 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54165973, COSV54166414; called by muse, mutect2, varscan2
- SLC25A21 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780255591, COSV58723097; called by muse, mutect2, varscan2
- SLC25A34 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 182/472 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372158085; called by muse, varscan2
- SLC29A2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs146921129; called by muse, mutect2, varscan2
- SLC35G5 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs201582168, COSV55315897; called by muse, mutect2, varscan2
- SLC38A8 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs756903028, COSV55309958; called by muse, varscan2
- SLC40A1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 80/503 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.068); catalogued as rs758105683, COSV53722320; called by muse, mutect2, varscan2
- SLC44A3 | c.563C>T p.S188F (on ENST00000271227 / NM_001114106.3; = p.S140F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54733886; called by muse, mutect2, varscan2
- SLC5A4 | c.1129+1G>A p.X377_splice | Splice Site (SNP) | VAF 137/358 reads (38%) | catalogued as rs750052634, COSV99832243; called by muse, mutect2, varscan2
- SLC5A8 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 143/277 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1346555854, COSV73311409; called by muse, mutect2, varscan2
- SLC9C1 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 117/296 reads (40%) | catalogued as COSV59888660; called by muse, mutect2, varscan2
- SLC9C2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs267598172, COSV62945331; called by mutect2, varscan2
- SLCO1B1 | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 42/232 reads (18%) | catalogued as COSV57006925, COSV57007024; called by muse, mutect2, varscan2
- SLCO1B3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV53933034, COSV53936843; called by muse, mutect2, varscan2
- SLITRK4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 166/232 reads (72%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV100567402; called by muse, mutect2, varscan2
- SMAD1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1247730282; called by muse, mutect2, varscan2
- SNAPC4 | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 139/347 reads (40%) | catalogued as COSV53732927; called by muse, mutect2, varscan2
- SNCAIP | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs187795054, COSV54401827; called by muse, mutect2, varscan2
- SNX19 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 157/343 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs431825173; ClinVar: not provided; called by muse, mutect2, varscan2
- SOGA1 | c.3751C>T p.R1251* | Nonsense Mutation (SNP) | VAF 85/555 reads (15%) | catalogued as COSV52919764; called by muse, mutect2, varscan2
- SORCS3 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63823736; called by muse, mutect2, varscan2
- SPAG17 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100309953; called by muse, mutect2, varscan2
- SPHKAP | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs754224869, COSV60884372; called by muse, mutect2, varscan2
- SPICE1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs147842972, COSV99870729; called by muse, mutect2, varscan2
- SPTA1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 92/458 reads (20%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.949); catalogued as COSV63760336; called by muse, mutect2, varscan2
- SRBD1 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 114/418 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200459688; called by muse, mutect2, varscan2
- SREBF2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 100/822 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs763739852; called by muse, mutect2, varscan2
- SRGAP3 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 115/441 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.651); catalogued as rs761802559, COSV64540064; called by muse, mutect2, varscan2
- SSRP1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs767096415; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 295/569 reads (52%) | PolyPhen probably damaging (0.999); catalogued as rs1222512954; called by muse, mutect2, varscan2
- STAB1 | c.4187G>A p.G1396E | Missense Mutation (SNP) | VAF 52/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868016633, COSV58742073; called by muse, varscan2
- STAB1 | c.4192G>A p.G1398R | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347598; called by muse, varscan2
- STAT1 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV63114971; called by muse, mutect2, varscan2
- STAU1 | c.518G>A p.G173E (on ENST00000371856 / NM_001319135.1; = p.G92E on NM_004602.3) | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV61460625; called by muse, mutect2
- STIL | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54551721; called by muse, mutect2, varscan2
- STOX2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 122/367 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1246197618, COSV57849084; called by muse, mutect2, varscan2
- STPG3 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 234/567 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200313176; called by muse, mutect2, varscan2
- SUSD2 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 186/490 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs946503853; called by muse, mutect2, varscan2
- SV2B | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100370548; called by muse, mutect2, varscan2
- SYNE1 | c.25682G>A p.G8561D (on ENST00000367255 / NM_182961.4; = p.G8513D on NM_033071.3) | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.807); catalogued as rs989761595; called by muse, mutect2, varscan2
- SYNPO2 | c.3392C>A p.P1131H | Missense Mutation (SNP) | VAF 114/372 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61116370; called by mutect2, varscan2
- SYT4 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 144/417 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV54899556, COSV54900275; called by muse, mutect2, varscan2
- TAF1L | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 77/704 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV54260255; called by muse, mutect2, varscan2
- TAMALIN | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53337012; called by muse, mutect2, varscan2
- TBC1D30 | c.1324C>T p.P442S (on ENST00000542120; = p.P279S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs945679332; called by muse, mutect2, varscan2
- TBX19 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 63/595 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs758812467; called by muse, mutect2, varscan2
- TDRD5 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 128/443 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54239402; called by muse, mutect2, varscan2
- TDRD6 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 233/414 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs755156872; called by muse, mutect2, varscan2
- TDRD9 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV59147203; called by muse, mutect2, varscan2
- TENT5C | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 322/610 reads (53%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); catalogued as rs773285739, COSV65615907; called by muse, mutect2, varscan2
- TEX26 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs34860357; called by muse, mutect2, varscan2
- THAP4 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as rs765431394; called by muse, mutect2, varscan2
- THRAP3 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 180/542 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs746007104, COSV63566869; called by mutect2, varscan2
- TIAF1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs368933068; called by muse, mutect2, varscan2
- TMC3 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as rs774243935; called by muse, mutect2, varscan2
- TMCC3 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs773260928, COSV99705239; called by muse, mutect2, varscan2
- TMEM215 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 237/539 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs141893993; called by muse, mutect2, varscan2
- TMEM44 | c.1192G>T p.G398W (on ENST00000392432 / NM_001166305.2; = p.G351W on NM_138399.5) | Missense Mutation (SNP) | VAF 208/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56447325; called by mutect2, varscan2
- TMEM94 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs755806504, COSV104395998; called by muse, mutect2
- TMPRSS11E | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373417678; called by muse, mutect2, varscan2
- TNFAIP3 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 385/639 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52797898; called by muse, mutect2, varscan2
- TNRC6A | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 237/489 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs758756773, COSV59363579; called by muse, mutect2, varscan2
- TNS1 | c.4514C>T p.S1505L | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs763763057, COSV50708536; called by muse, mutect2, varscan2
- TNXB | c.8893G>A p.E2965K (on ENST00000647633; = p.E2718K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.81); catalogued as rs771115433; called by muse, mutect2, varscan2
- TP53 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 226/512 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695595, COSV52787732; called by muse, mutect2, varscan2
- TPCN1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs143865064; called by muse, mutect2, varscan2
- TPSG1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs770021673, COSV99326699; called by muse, mutect2, varscan2
- TPTE | c.1552C>G p.L518V (on ENST00000618007 / NM_199261.4; = p.L500V on NM_199259.4) | Missense Mutation (SNP) | VAF 106/502 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs776836004; called by muse, varscan2
- TRAPPC9 | c.1768+1G>A p.X590_splice | Splice Site (SNP) | VAF 64/196 reads (33%) | catalogued as rs765002341; called by muse, mutect2
- TRHR | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs750828177, COSV61234355; called by muse, varscan2
- TRHR | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs147214548, COSV61234235; called by muse, mutect2, varscan2
- TRIM10 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 68/351 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs368813408; called by muse, mutect2, varscan2
- TRIM11 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 124/533 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs1319457913; called by muse, mutect2, varscan2
- TRIM23 | c.1308T>C p.I436= | Splice Region (SNP) | VAF 79/210 reads (38%) | catalogued as rs1284310147; called by muse, mutect2, varscan2
- TRIO | c.5266C>A p.H1756N | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60084732; called by mutect2, varscan2
- TRMU | c.162_163del p.C54* | Frame Shift Del (DEL) | VAF 169/561 reads (30%) | catalogued as rs1441183063; called by pindel, varscan2
- TRPC4AP | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV52684561; called by muse, mutect2, varscan2
- TRPV6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 140/506 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs866319889; called by muse, mutect2, varscan2
- TTBK1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52489501; called by muse, mutect2, varscan2
- TTLL5 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 120/321 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs776388722; called by muse, mutect2, varscan2
- TTN | c.93508C>T p.R31170C (on ENST00000591111; = p.R23746C on NM_003319.4) | Missense Mutation (SNP) | VAF 139/459 reads (30%) | PolyPhen possibly damaging (0.897); catalogued as rs371807358; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.33472G>A p.E11158K (on ENST00000591111; = p.E10231K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/219 reads (38%) | PolyPhen benign (0.418); catalogued as COSV59960368; called by muse, mutect2, varscan2
- TTN | c.23275G>A p.E7759K (on ENST00000591111; = p.E6832K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/268 reads (43%) | PolyPhen possibly damaging (0.894); catalogued as COSV59934013; called by muse, mutect2, varscan2
- TUBA8 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 228/589 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773585722; called by muse, mutect2, varscan2
- TULP3 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 177/329 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377154908; called by muse, mutect2, varscan2
- UBE4A | c.2944G>A p.E982K (on ENST00000252108 / NM_001204077.2; = p.E989K on NM_004788.4) | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99348519; called by muse, mutect2, varscan2
- UBN1 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 73/314 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs140433399, COSV52174067, COSV99278767; called by muse, mutect2, varscan2
- UGT2B4 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100522623; called by muse, mutect2, varscan2
- UNC5B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 230/522 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.226); catalogued as COSV58980607; called by muse, mutect2, varscan2
- USP17L1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV73252905; called by muse, mutect2, varscan2
- USP2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 90/427 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99489802; called by muse, mutect2, varscan2
- USP49 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1032446541, COSV99789994; called by muse, mutect2, varscan2
- UTY | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 168/212 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs1458426078; called by muse, mutect2, varscan2
- VCAN | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 147/369 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1037404199; called by muse, mutect2, varscan2
- VPS13B | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62018957; called by muse, mutect2, varscan2
- VWA3A | c.3389G>A p.G1130D | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs770040448; called by muse, varscan2
- VWDE | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 139/371 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs748729012, COSV51724730; called by muse, mutect2, varscan2
- VWDE | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51723903; called by muse, mutect2, varscan2
- VWF | c.466A>C p.N156H | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54633518; called by muse, mutect2, varscan2
- WDR53 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 214/449 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100218031; called by muse, mutect2, varscan2
- WDR72 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64743956; called by muse, mutect2, varscan2
- WIPF3 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 83/458 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as rs375082324; called by muse, mutect2, varscan2
- XIRP2 | c.1279G>A p.G427S (on ENST00000628543; = p.G602S on NM_152381.6) | Missense Mutation (SNP) | VAF 221/484 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as rs1421282811; called by muse, mutect2, varscan2
- XPC | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 168/570 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs202160303; called by muse, mutect2, varscan2
- XYLT1 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV54486106; called by muse, mutect2, varscan2
- ZC3H13 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 218/502 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.03); catalogued as rs1247265797, COSV54464025; called by muse, mutect2, varscan2
- ZC3H7B | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV60963711; called by muse, mutect2, varscan2
- ZFYVE16 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); catalogued as COSV62016015; called by muse, mutect2, varscan2
- ZMAT4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.771); catalogued as rs1469992456, COSV52691310; called by muse, mutect2, varscan2
- ZMYM1 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 137/436 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.886); catalogued as rs759972113; called by muse, mutect2, varscan2
- ZNF277 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 288/604 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62463315; called by muse, mutect2, varscan2
- ZNF319 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 153/422 reads (36%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.505); catalogued as rs1048312851; called by muse, mutect2, varscan2
- ZNF425 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 97/404 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs758029795; called by muse, mutect2, varscan2
- ZNF480 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs765030300, COSV57996984; called by muse, mutect2, varscan2
- ZNF483 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 168/508 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs759118960, COSV58514376; called by muse, mutect2, varscan2
- ZNF512B | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 150/294 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV53868272; called by muse, mutect2, varscan2
- ZNF513 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 166/608 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1444034354; called by muse, varscan2
- ZNF527 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464630440; called by muse, mutect2, varscan2
- ZNF534 | c.913C>T p.H305Y (on ENST00000332323 / NM_001143939.3; = p.H292Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/317 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs267605633, COSV56514865; called by muse, mutect2, varscan2
- ZNF565 | c.757C>T p.H253Y (on ENST00000355114; = p.H213Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/417 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs141296440, COSV58411709; called by muse, mutect2, varscan2
- ZNF584 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 219/457 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs766119407; called by muse, mutect2, varscan2
- ZNF679 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 239/468 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV55376753, COSV55382350; called by muse, mutect2, varscan2
- ZNF727 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 243/437 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs1183702814; called by muse, varscan2
- ZNF729 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1228156365; called by muse, mutect2, varscan2
- ZNF773 | c.532T>G p.S178A | Missense Mutation (SNP) | VAF 181/378 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV56587727; called by muse, mutect2, varscan2
- ZNF816 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 175/356 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs774872949; called by muse, mutect2, varscan2
- ZNF844 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370550025; called by muse, mutect2, varscan2
- ZNF90 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); catalogued as COSV69001758; called by muse, mutect2, varscan2
- ZNF91 | c.2536del p.I846* | Frame Shift Del (DEL) | VAF 41/284 reads (14%) | catalogued as COSV56082892; called by mutect2, pindel, varscan2
- ZNFX1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 70/1040 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs893443763; called by muse, mutect2
- ZP4 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 184/441 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63911377, COSV63912224; called by muse, mutect2, varscan2
- AATF | c.1401C>T p.L467= | Splice Region (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- ABCF1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG1 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- ABHD16B | c.656_658del p.D219del | In Frame Del (DEL) | VAF 271/557 reads (49%) | called by pindel, varscan2
- ABL1 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 217/498 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACACA | c.1056del p.G353Efs*33 | Frame Shift Del (DEL) | VAF 41/263 reads (16%) | called by mutect2, pindel, varscan2
- ACACB | c.4559T>A p.M1520K | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- ACBD4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ACTR2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTR8 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ADAD2 | c.1663G>A p.E555K (on ENST00000315906 / NM_001145400.2; = p.E637K on NM_139174.4) | Missense Mutation (SNP) | VAF 141/360 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ADAMTS16 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADAMTS18 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 130/419 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS8 | c.1098G>A p.G366= | Splice Region (SNP) | VAF 86/230 reads (37%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAP1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 130/433 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ADCY1 | c.2258T>C p.M753T | Missense Mutation (SNP) | VAF 238/504 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- ADCY8 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADCY8 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 153/459 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ADGRD1 | c.492C>T p.G164= | Splice Region (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- ADGRE1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE1 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADGRL2 | c.4015C>T p.P1339S (on ENST00000370717 / NM_001366005.1; = p.P1283S on NM_012302.4) | Missense Mutation (SNP) | VAF 234/416 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRV1 | c.12928G>A p.E4310K | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- AGL | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- AHCTF1 | c.4984_4986del p.V1662del (on ENST00000366508; = p.V1636del on NM_015446.5) | In Frame Del (DEL) | VAF 90/445 reads (20%) | called by mutect2, pindel*, varscan2*
- AK7 | c.980T>A p.L327* | Nonsense Mutation (SNP) | VAF 110/263 reads (42%) | called by muse, mutect2, varscan2
- AKT3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 119/362 reads (33%) | called by muse, mutect2, varscan2
- AL136295.1 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 376/600 reads (63%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ALDH1A1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 171/429 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ALDH2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALLC | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 153/331 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPG | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by mutect2, varscan2
- ALPP | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by mutect2, varscan2
- AMPD3 | c.143C>T p.P48L (on ENST00000396553 / NM_001025389.2; = p.P57L on NM_000480.3) | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.5821G>A p.D1941N | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ANK3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD2 | c.540C>T p.F180= | Splice Region (SNP) | VAF 91/289 reads (31%) | called by muse, mutect2, varscan2
- ANKRD31 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ANKS1A | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO4 | c.1387G>A p.E463K (on ENST00000392977 / NM_001286615.2; = p.E428K on NM_178826.4) | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ANO6 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOBR | c.2573G>A p.G858E (on ENST00000431282; = p.G867E on NM_018690.4) | Missense Mutation (SNP) | VAF 198/439 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); called by muse, varscan2
- ARAP2 | c.3029T>G p.L1010* | Nonsense Mutation (SNP) | VAF 185/377 reads (49%) | called by muse, mutect2, varscan2
- ARAP3 | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 100/320 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP32 | c.4004C>T p.S1335F (on ENST00000310343 / NM_001378025.1; = p.S986F on NM_014715.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ARHGEF12 | c.4486T>C p.C1496R | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF28 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ARHGEF28 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARRDC4 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASAP2 | c.1839C>G p.N613K | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASTN1 | c.806C>G p.T269R | Missense Mutation (SNP) | VAF 231/487 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ASTN2 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 223/693 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATF2 | c.814T>C p.S272P | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- ATF7IP | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 179/347 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP13A1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 78/389 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ATP8B2 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 314/609 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUTS2 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BCL11B | c.2219C>T p.S740L (on ENST00000357195 / NM_001282237.2; = p.S669L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/639 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- BDP1 | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BICD1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- BIRC6 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BMP3 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BRWD1 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BUD23 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 294/489 reads (60%) | called by muse, mutect2, varscan2
- C10orf88 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- C17orf99 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 554/667 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C19orf44 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 154/287 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1orf127 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 185/478 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 108/402 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- C2orf16 | c.2489A>G p.K830R | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C3orf22 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 159/450 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by mutect2, varscan2
- CACNA1D | c.1975C>T p.L659F (on ENST00000350061 / NM_001128840.3; = p.L679F on NM_000720.4) | Missense Mutation (SNP) | VAF 178/444 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CACNG3 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CAPN11 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CAPN14 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CAPN8 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CATSPER4 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 258/685 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CCBE1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC110 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC150 | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC152 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC152 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC184 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 263/508 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.261); called by muse, varscan2
- CCDC184 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 261/506 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.261); called by muse, varscan2
- CCDC184 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 106/487 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); called by muse, varscan2
- CCDC22 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 107/152 reads (70%) | called by muse, mutect2, varscan2
- CCDC39 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCDC74A | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 139/365 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNQ | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 118/160 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CD101 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 196/343 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CD163L1 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 80/508 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD22 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 118/553 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD300E | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 499/659 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CD4 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CDH12 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CDH18 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 83/516 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CDH20 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH8 | c.2130A>C p.Q710H | Missense Mutation (SNP) | VAF 171/469 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDHR1 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKL1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CELSR3 | c.7951G>A p.G2651S | Missense Mutation (SNP) | VAF 235/508 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPF | c.4289C>T p.S1430F | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- CEP104 | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 127/336 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CEP170B | c.1570C>T p.P524S (on ENST00000453495; = p.P453S on NM_015005.3) | Missense Mutation (SNP) | VAF 171/469 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CEP290 | c.3183dup p.L1062Afs*8 | Frame Shift Ins (INS) | VAF 173/392 reads (44%) | called by mutect2, pindel, varscan2
- CEP295 | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CERS6 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CFAP46 | c.5081G>A p.R1694K | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP46 | c.1743G>A p.W581* | Nonsense Mutation (SNP) | VAF 101/337 reads (30%) | called by muse, mutect2, varscan2
- CFAP54 | c.2081T>A p.V694E | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP54 | c.2703A>T p.R901S | Missense Mutation (SNP) | VAF 229/391 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHAMP1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 161/516 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CHD9 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHD9 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CHKB | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 179/454 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); called by mutect2, varscan2
- CHN1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CITED4 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 225/502 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCNKB | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 241/634 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLCNKB | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- CLK3 | c.1373C>T p.S458L (on ENST00000395066 / NM_001130028.1; = p.S310L on NM_003992.4) | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CLSPN | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 160/458 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CMYA5 | c.3260C>T p.S1087L | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL27A1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 327/641 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL2A1 | c.4201G>C p.D1401H | Missense Mutation (SNP) | VAF 70/355 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A4 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 149/377 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- COL4A6 | c.3190C>T p.L1064F | Missense Mutation (SNP) | VAF 110/151 reads (73%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COLCA2 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPA4 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 225/456 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CPVL | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 108/251 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CPZ | c.1436C>T p.P479L (on ENST00000360986 / NM_001014447.3; = p.P468L on NM_003652.3) | Missense Mutation (SNP) | VAF 91/407 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB1 | c.3115C>T p.L1039F | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, varscan2
1,204 further variants in this file (502 protein-altering or splice-affecting, 626 silent, 76 other) are not listed here.
